HCMI case HCM-CSHL-0403-C25 — NCI Cancer Model Development for the Human Cancer Model Initiative (HCMI-CMDC)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Ductal and Lobular Neoplasms; Primary site: Pancreas. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/943e817d-37f3-4df0-84c5-d572ca3de923

Demographics
Sex at birth: male; Race: white; Ethnicity: not hispanic or latino; Year of birth: 1954; Vital status: Dead; Days to death: 743 days (2.0 years); Cause of death: Cancer Related.

Diagnoses (1)
1. Infiltrating duct carcinoma, NOS: ICD-O-3 morphology code: 8500/3; ICD-10 code: C25.9; Tissue or organ of origin: Pancreas, NOS; Site of resection or biopsy: Head of pancreas; Classification of tumor: primary; Age at diagnosis: 63.9 years (23,352 days); AJCC staging edition: 8th; AJCC clinical stage: Stage IB; AJCC pathologic T: T2; AJCC pathologic N: N0; AJCC pathologic M: M0; AJCC pathologic stage: Stage IB; Tumor grade: G2; Prior malignancy: no; Prior treatment: No.
   Pathology details: Peripancreatic lymph nodes positive: 0; Peripancreatic lymph nodes tested: 14.
   Treatment given: Treatment type: Surgery, NOS; Initial disease status: Initial Diagnosis; Days to treatment start: 36 days.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Fluorouracil + Irinotecan Hydrochloride + Leucovorin Calcium + Oxaliplatin; Treatment intent type: Adjuvant; Initial disease status: Residual Disease; Regimen or line of therapy: FOLFIRINOX; Days to treatment start: 454 days (1.2 years); Days to treatment end: 517 days (1.4 years).
   Treatment given: Treatment type: Radiation, Mixed Photon Beam; Treatment intent type: Adjuvant; Initial disease status: Residual Disease; Days to treatment start: 466 days (1.3 years); Days to treatment end: 470 days (1.3 years).
   Recorded as not given: neoadjuvant treatment (type not reported); adjuvant Immunotherapy (Including Vaccines), for residual disease; adjuvant Targeted Molecular Therapy, for residual disease.

Follow-up (2 entries)
- Days to follow up: 683 days (1.9 years); Disease response: Progressive Disease; Progression or recurrence: Yes.
- Follow-up contact recording only the day: day 354.

Molecular and laboratory tests
- CA19-9: 253.7.

Other clinical attributes
- Timepoint category: Initial Diagnosis; Weight: 74.8 kg; Height: 182.9 cm; BMI: 22.

Exposures
- Tobacco smoking status: Current Reformed Smoker for < or = 15 yrs; Alcohol intensity: Lifelong Non-Drinker; Alcohol days per week: 0.

Family history
- Relative with cancer history: no.

Biospecimens (3 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample HCM-CSHL-0403-C25-01B: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
  Slide HCM-CSHL-0403-C25-01B-01-S2-HE: Section location: Bottom; Percent tumor cells: 50; Percent tumor nuclei: 60; Percent normal cells: 25; Percent necrosis: 0; Percent stromal cells: 25; Percent lymphocyte infiltration: 0; Percent monocyte infiltration: 0; Percent neutrophil infiltration: 0.
  Slide HCM-CSHL-0403-C25-01B-01-S1-HE: Section location: Top; Percent tumor cells: 35; Percent tumor nuclei: 50; Percent normal cells: 35; Percent necrosis: 0; Percent stromal cells: 30; Percent lymphocyte infiltration: 0; Percent monocyte infiltration: 0; Percent neutrophil infiltration: 0.
- Sample HCM-CSHL-0403-C25-10A: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Buffy Coat; Preservation method: Frozen.
- Sample HCM-CSHL-0403-C25-85D: Sample type: Next Generation Cancer Model; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: 3D Organoid; Preservation method: Frozen; Passage count: 12.
